Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9LB, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9LB-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
JW 1/23/14

Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

Gross description:

1. (Prostate gland): Prostate gland: Weight: 51 g, Volume: 45 ml, Size: 4 x 5 x 3.2 cm. Adherent seminal vesicles and deferent duct: right side: 2.5 cm, left side: 2.4 cm. The surface is marked with green ink on the right side, blue ink on the left side. Apical peri-urethral a funnel shaped 2.5 x 0.8 cm tissue defect marked with red ink. Total of the cross sections: 1 cm.
2. (Lymph nodes, right side): 6.5 x 5 x 1 cm measuring adipose tissue containing 3 nodes measuring up to 4 cm.
3. (Lymph nodes, left side): 4.3 x 3.5 x 1.5 cm measuring adipose tissue containing 1 nodes measuring up 6.5 cm.

Microscopy:

1. Apex right and left: Right 8 tissue blocks, left 7 tissue blocks (total 15 tissue blocks). 2 cross sections: Right 10 tissue blocks, left 9 tissue blocks (total 19 tissue blocks). Basis right and left: Right 8 tissue blocks, left 7 tissue blocks (total 15 tissue blocks). Seminal vesicles right and left: Right 2 tissue blocks, left 2 tissue blocks (total 4 tissue blocks). Deferent ducts right and left: Right 1 tissue blocks, left 1 tissue blocks (total 2 tissue blocks).
2. Frozen lymph nodes right: 10 tissue blocks.
3. Frozen lymph nodes left: 6 tissue blocks.

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 60%, Gleason 4: 40%). Tumor involves both lobes with the main focus on the right side. Maximum tumor diameter: 48 mm. Perineural invasion. Tumor infiltration into peri-prostatic adipose tissue in 4 tissue blocks with the main focus around the right seminal vesicle (maximum invasion length 4 mm, maximal invasion depth 3 mm). Positive surgical margin in 6 blocks with the main focus around the right seminal vesicle (contact length 1.2 mm; Gleason 5). Negative peri-urethral surgical margin. Tumor infiltration into both seminal vesicles. Tumor-free deferent ducts.

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia.

In addition, fibromuscular soft tissue with extensive infiltration of the carcinoma.

2. (Lymph nodes, right side): Six tumor-free lymph nodes (0/6).

[page 2 of 2]
3. (Lymph nodes, left side): Three tumor-free lymph nodes (0/3).

Tumor classification

(in consideration of the immunohistochemical analyses):

pT3b, Gleason 5+4=9 (Gleason 5: 60%, Gleason 4: 40%), maximum tumor diameter: 48 mm, tumor volume approx. 30.2 ml (Gleason 5: 18.1 ml, Gleason 4: 12.1 ml), pN0 (0/9), L1, V0, R1

Comments:

Tumor infiltration into peri-prostatic adipose tissue in 4 tissue blocks (AR3B, SBR1, SBR2, SBL1) with main focus around the right seminal vesicle (tissue block SBR1/SBR2).

Positive surgical margin in 6 tissue blocks (AL2B, L1C, BL2B, BL3A, SBR2, SBL2) with main focus around the right seminal vesicle (block SBR2).

Immunohistochemical analyses (AE1/AE3) on lymph nodes (tissue blocks 2A, 2C, 3E and 3B) revealed no metastases.

Immunohistochemical analyses (D2-40, CD31) on tissue blocks SBR2 an SBL2 revealed lymphatic invasion.

One macroscopic image for tumor mapping.

Source: NCI Genomic Data Commons file e0daecb1-13e2-4fbc-ad92-b90658481d75 (TCGA-ZG-A9LB.224AC4AB-11CC-4832-90FD-937C3C7B4C8E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).